Somatic mutation profile of tumor specimen TCGA-3C-AALK-01A (aliquot TCGA-3C-AALK-01A-11D-A41F-09) from TCGA case TCGA-3C-AALK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.2 years (19,074 days).
Specimen TCGA-3C-AALK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62c48aed-bc6f-40b7-b934-b11b8f42cfcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3C-AALK-10A (Blood Derived Normal), aliquot TCGA-3C-AALK-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5056a39-67d7-420c-82fc-3a086b6ec75e

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 9, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3012G>T p.M1004I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV55881019, COSV55891097; called by muse, mutect2, varscan2
- ADGRE1 | c.771G>T p.L257F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.717); catalogued as COSV51672730, COSV99165027; called by muse, mutect2
- ALDH9A1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs142168163; called by muse, mutect2, varscan2
- CAST | c.1106T>C p.I369T (on ENST00000341926; = p.I452T on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs145309877; called by muse, mutect2, varscan2
- CDH10 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs767347173, COSV52594895; called by muse, mutect2, varscan2
- CDH20 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99404298; called by muse, mutect2, varscan2
- CLEC1A | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV59531431; called by muse, mutect2
- CXCR2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs776039485, COSV59280727; called by muse, mutect2, varscan2
- EEPD1 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as COSV99631747; called by muse, mutect2, varscan2
- EPB41L1 | c.2459C>G p.S820C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99148926; called by mutect2, varscan2
- FREM1 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs369488195, COSV66527572; called by muse, mutect2
- FSIP2 | c.17434T>C p.C5812R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV100553972; called by muse, mutect2, varscan2
- H2BC13 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.014); catalogued as COSV100704314; called by mutect2, varscan2
- HUWE1 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99470588; called by muse, mutect2, varscan2
- IRX2 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.202); catalogued as rs575915597, COSV100121569; called by muse, mutect2, varscan2
- KCNQ2 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100609660; called by muse, mutect2, varscan2
- LRIT1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs140648210, COSV100812854; called by mutect2, varscan2
- MAP2K4 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV62255065; called by muse, mutect2, varscan2
- MEI1 | c.1148T>C p.I383T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs764979273, COSV100299587; called by muse, mutect2, varscan2
- MYORG | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99898338; called by muse, mutect2, varscan2
- NCOR1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99247216; called by muse, mutect2, varscan2
- PCDHB11 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV100696895; called by muse, mutect2, varscan2
- PDGFC | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99924755; called by muse, mutect2
- PLEKHA1 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as rs1022886017, COSV64569520; called by muse, mutect2
- RBMXL1 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53101168, COSV99555467; called by muse, mutect2, varscan2
- SGSM1 | c.2244G>C p.E748D (on ENST00000400359 / NM_001039948.4; = p.E687D on NM_133454.3) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100771848, COSV63082496; called by muse, mutect2, varscan2
- SLC18A2 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV100041344, COSV53688974; called by mutect2, varscan2
- STAT6 | c.2233C>G p.L745V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.055); catalogued as COSV100272512; called by muse, mutect2, varscan2
- STPG4 | c.334G>C p.V112L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs150323269; called by muse, mutect2, varscan2
- TCTE3 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774340519, COSV100825360; called by muse, mutect2, varscan2
- THBS2 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.05); catalogued as rs142358231; called by muse, mutect2, varscan2
- USP32 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100341416; called by muse, mutect2, varscan2
- WDR49 | c.1079G>A p.R360H (on ENST00000308378 / NM_001366158.1; = p.R701H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs199677479; called by muse, mutect2, varscan2
- XPOT | c.2519T>A p.I840N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100225332; called by muse, mutect2, varscan2
- ZFP2 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63724541; called by muse, mutect2
- ZFYVE16 | c.4188-1G>C p.X1396_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as COSV100566193; called by muse, mutect2, varscan2
- ZNF169 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV100566130; called by muse, mutect2, varscan2
- CCDC91 | c.873_876del p.C291Wfs*12 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- DHX29 | c.4108_4109del p.*1370Kfs*12 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- H2AC15 | c.252dup p.Q85Afs*16 | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- ACTRT1 | c.96C>T p.R32= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100947505; called by muse, mutect2
- HECTD4 | c.3271C>T p.L1091= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100295806; called by muse, mutect2, varscan2
- LPO | c.1134G>T p.L378= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99228340; called by muse, mutect2, varscan2
- MIA2 | c.40C>T p.L14= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- OPA3 | c.507C>T p.S169= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs757829968, COSV54400615; called by muse, mutect2, varscan2
- OR7D2 | c.846C>A p.T282= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100712938; called by muse, mutect2, varscan2
- PRRX2 | c.276G>A p.P92= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100991160; called by mutect2, varscan2
- SLC18A3 | c.1104C>T p.G368= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1280312684, COSV60326135; called by muse, mutect2, varscan2
- TBR1 | c.600G>A p.V200= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV101271402; called by muse, mutect2
- MIR221 | n.42G>T | RNA (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- TBX2 | chr17:61412289 C>T | 3'Flank (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
